TCGA case TCGA-FD-A3SL — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: BLN - University Of Chicago. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4570b6e2-d430-41ca-aab1-ce4d14c36463

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Dead; Days to death: 712 days (1.9 years).

Diagnoses (4)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.4; Tissue or organ of origin: Posterior wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 60.3 years (22,020 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lung, NOS / Colon, NOS.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: Yes; Lymph nodes positive: 18; Lymph nodes tested: 18; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine; Days to treatment start: 302 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Papillary transitional cell carcinoma, non-invasive: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Solution; Treatment intent type: Induction; Timepoint category: Prior to Procurement.
3. Prior malignancy of the bladder (histology not recorded by GDC). Age at diagnosis: 60.3 years (22,020 days).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 0 days; Treatment anatomic sites: Bladder.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lung, NOS. Age at diagnosis: 61.0 years (22,280 days); Days to diagnosis: 260 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Day 260 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 260 days.
- Days to follow up: 334 days; Disease response: With Tumor.
- Days to follow up: 683 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 712 days (1.9 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 116 kg; Height: 183 cm; BMI: 34.6.

Exposures
- Occupation type: Locomotive Engine Drivers and Related Workers.
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FD-A3SL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 920 mg.
  Slide TCGA-FD-A3SL-01A-02-TSB: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FD-A3SL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FD-A3SL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: retired; Occupation primary: railroad worker; Occupation primary industry: railroad industry; Tobacco smoking history indicator: 1; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Dome; Anatomic organ subdivision: Wall Anterior; Anatomic organ subdivision: Wall Posterior; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Metastatic site other: ileocecum; Incidental prostate cancer indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: Yes; Noninvasive bladder CA treatment type: Bacillus Calmette-Guerin (BCG); Bcg treatment 90 days prior to resection: No; Bcg treatment complete response: No; Bcg treatment induction courses indicator: Yes; Bcg treatment maintenance courses indicator: Yes.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.
- Other malignancy form: Malignancy type: Prior Malignancy.
- Other malignancy form, Surgery: Other malignancy surgery type: Turbt.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 712 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 712 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 260 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FD-A3SL-01A-21D-A22Y-01): tumor purity 0.42, ploidy 3.69, whole-genome doublings 1.
